MMRF case MMRF_2124 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/889d29c9-36d6-43f3-a86a-11773e5b7191

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 55 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 55.2 years (20,165 days); ISS stage: III; Days to last known disease status: 903 days (2.5 years); Days to last follow up: 903 days (2.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 20 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 21 days; Days to treatment end: 159 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 167 days; Days to treatment end: 167 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 280 days; Days to treatment end: 679 days (1.9 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 679 days (1.9 years); Days to treatment end: 762 days (2.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 763 days (2.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 2): M Protein 5.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 163 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.5 mg/dL; Immunoglobulin G 68.9 g/L; Immunoglobulin A 0.434 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 10.4 µg/mL; Lactate Dehydrogenase 4.85 µkat/L; Hemoglobin 5.27 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 114 ×10⁹/L; Creatinine 271 µmol/L; Blood Urea Nitrogen 14.3 mmol/L; Calcium 3.75 mmol/L; Albumin 35 g/L; Total Protein 11.4 g/dL; Glucose 6.6 mmol/L.
- Day 103 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 4.12 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 414 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2 mmol/L; Albumin 35 g/L; Total Protein 5.6 g/dL; Glucose 9.19 mmol/L.
- Day 187 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 2.35 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.8 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 78 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 5.9 g/dL; Glucose 5.56 mmol/L.
- Day 267 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Immunoglobulin G 2.53 g/L; Immunoglobulin A 0.265 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.45 mmol/L; Albumin 47 g/L; Total Protein 6.7 g/dL; Glucose 4.9 mmol/L.
- Day 336 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.6 mg/dL; Immunoglobulin G 2.61 g/L; Immunoglobulin A 0.321 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 115 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.13 mmol/L; Albumin 37 g/L; Total Protein 5.6 g/dL; Glucose 5.06 mmol/L.
- Day 455 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0 mg/dL; Immunoglobulin G 1.04 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 71 ×10⁹/L; Creatinine 119 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 5.6 g/dL; Glucose 5.17 mmol/L.
- Day 539 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0 mg/dL; Immunoglobulin G 7.49 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 102 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 5.34 mmol/L.
- Day 623 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.6 mg/dL; Immunoglobulin G 7.62 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 72 ×10⁹/L; Creatinine 144 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 6.2 g/dL; Glucose 6 mmol/L.
- Day 707 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.6 mg/dL; Immunoglobulin G 8.62 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 83 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.15 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 5.61 mmol/L.
- Day 763 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 6.1 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 90 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 4.02 mmol/L.
- Day 903 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.6 mg/dL; Immunoglobulin G 6.84 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 114 ×10⁹/L; Creatinine 117 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.15 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 4.95 mmol/L.

Other clinical attributes
- Day 1: Weight: 65 kg; Height: 157 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lung Cancer.
- Relative with cancer history: yes; Relationship type: Child.

Biospecimens (2 samples)
- Sample MMRF_2124_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2124_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
